Surgical pathology report (de-identified scan), TCGA case TCGA-49-6743, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-6743-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT

COLLECTION DATE/TIME: [REDACTED]

1st Specimen collected on [REDACTED]

Accessioned on [REDACTED]

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1. LYMPH NODE, R4 (RESECTION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. NEGATIVE FOR CARCINOMA.

2. LYMPH NODE, L4 (RESECTION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. NEGATIVE FOR CARCINOMA.

3. LUNG, RIGHT UPPER LOBE (LOBECTOMY):

SPECIMEN TYPE:

Lobectomy

TUMOR SITE:

Right upper lobe

HISTOLOGIC TYPE:

Adenocarcinoma, solid type with clear cell change

TUMOR SIZE:

Greatest dimension: 7.5 cm

HISTOLOGIC GRADE:

G3: Poorly differentiated

LYMPH NODES:

All 17 nodes negative for tumor (includes parts 1-7)

DIRECT EXTENSION OF TUMOR:

The tumor extends subpleurally but does not involve the pleural surface

EXTENT OF INVASION (7th Edition, AJCC):

PRIMARY TUMOR:

pT3: Tumor which is >7 cm or invades chest wall, diaphragm, mediastinal pleura, or parietal pericardium, or involves main bronchus <2 cm from carina or associated with total atelectasis or separate tumor nodule in the same lobe

REGIONAL LYMPH NODES:

pN0: No regional lymph node metastasis

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from nearest margin: 4.0 cm (bronchial margin)

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Absent

LYMPHATIC (SMALL VESSEL) INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Immunohistochemistry demonstrates that the tumor cells are TTF-1 (diffuse) and Napsin-A (variable) positive. An immunostain for p63 shows patchy, variable staining of the tumor cells. Thsi staining

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
LAB RESULTS

SP-CONS - SURG PATH REPORT -

pattern supports the diagnosis.

Background lung shows emphysematous changes and organizing lung injury (fibroblast foci) adjacent to the tumor.

4. LYMPH NODE, STATION 1 (RESECTION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

5. LYMPH NODE, R4 (RESECTION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

6. LYMPH NODE, 10R (RESECTION): THREE (3) LYMPH NODES, NEGATIVE FOR TUMOR.

7. LYMPH NODE, STATION 7 (RESECTION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Note: EGFR and KRAS mutation analysis studies are pending and will be reported separately.

ADDENDUM ----- Pathologist: KRAS MUTATION ANALYSIS IS NEGATIVE. NO MUTATIONS WERE IDENTIFIED AT CODONS 12 AND 13 OF THE KRAS GENE.

EGFR MUTATION ANALYSIS IS NEGATIVE. NO MUTATIONS WERE DETECTED AT EXONS 18-21 OF THE EGFR GENE

NOTE: A copy of the complete report is available in and is on file in the molecular pathology laboratory.

See Clinical Document dated for official report.

Reported by: Surgical Pathology

Final Report Signed on
Addendum added on

Source: NCI Genomic Data Commons file cc1747b9-f97a-4fb4-893a-7eaeb88f5f3b (TCGA-49-6743.BC777CB6-8409-4A25-A22A-A398C28EF065.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).